Surgical pathology report (de-identified scan), TCGA case TCGA-AX-A2HG, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-AX-A2HG-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report Temporary Copy

Page 1 of 3

Case: 1
Collected:
Ordered by:

Patient:
ID:
Location:

Clinical Information

Grade 2 adenocarcinoma of endometrium. TLH, BSO, lymph nodes

Organ Or Tissue

Left periaortic node
Right periaortic node
Right pelvic node
Left pelvic node
Uterus, cervix, BSO

ICD-0-3

adenocarcinoma, endometrioid, NOS

8380/3

Site: endometrium c54.1

for 6/19/11

Gross Description

The specimen is received in five parts.

Part A. is labeled with the patient's name, designated "left periaortic node". Received in formalin and consists of one lymph node and attached fibroadipose tissue that measure in aggregate 2.5 x 1.5 x 0.3 cm. The lymph node measure 1.3 x 0.7 x 0.4 cm. The specimen is entirely submitted in cassette A1.

Part B. is labeled with the patient's name, designated "right periaortic node". Received in formalin and consists of one lymph node and a fragment of adipose tissue that measure together 2.0 x 1.3 x 0.5 cm. The lymph node measure 1.4 x 0.7 x 0.5 cm. The specimen is entirely submitted in cassette B1.

Part C. is labeled with the patient's name, designated "right pelvic node". Received in formalin and consists of several fragments of adipose tissue and lymph nodes that measure in aggregate 8.0 x 7.0 x 1.5 cm. The specimen is dissected to identify several lymph nodes ranging in size from 0.3 cm in maximum dimension to 2.3 cm in maximum dimension. The lymph nodes are entirely submitted as follows:

- C1 - One lymph node bisected
- C2 - One lymph node bisected
- C3 - One lymph node bisected
- C4 - C6 Remainder of lymph nodes

Part D. is labeled with the patient's name "left pelvic nodes". Received in formalin and consists of several fragments of adipose tissue and lymph nodes that measure in aggregate 6.5 x 4.5 x 1.0 cm. The specimen is dissected to identify several lymph nodes ranging in size from 0.3 to 2.5 cm in maximum dimension. The lymph nodes are entirely submitted as follows:

- D1 - D5 One lymph node in each cassette
- D6 - remainder of the specimen

Part E. is labeled with the patient's name "uterus, cervix, BSO". Received fresh for intraoperative consultation, and consists of a uterus with attached cervix and bilateral adnexa. It weighs 207 gm. The uterus measures 9.0 x 6.0 x 6.0 cm. It is covered by a tan/pink smooth serosa. The exocervix measures 3.0 x 2.3 x 0.7 cm and has a 1.3 cm slit-like os. The endometrial cavity measures 6.0 x 6.0 cm. The endometrial cavity is almost entirely replaced by a polypoid tumor that measures 6.0 x 6.0 x 2.0 cm and involves entirely the anterior wall and 70% of the posterior wall. The tumor extends to the lower uterine segment in the anterior wall of the uterus. Cross section shows invasion of 1.3 cm into the myometrium. The average thickness of the myometrium is 2.4 cm. The left fallopian tube measures 3.5 cm in length x 0.7 cm in diameter. The serosal surface is tan/pink and smooth. The fimbria are present and appear unremarkable. The left ovary measures 1.8 x 1.0 x 0.7 cm, is tan/yellow and smooth and appear not involved by tumor. The cut surface is yellow and pink and

[page 2 of 3]
Surgical Pathology Report

Temporary Copy

Page 2 of 3

Case:

Collected:

Ordered by:

Patient

ID:

Location:

unremarkable. The right fallopian tube measures 3.5 cm in length x 0.5 cm in diameter. The fimbria are present and appear unremarkable. The fallopian tube is covered by a tan/pink, smooth serosa. The right ovary measures 2.0 x 1.0 x 0.6 cm, is pink/yellow and smooth. The cut surface is pink and yellow and appear not involved by tumor. The endocervical canal measures 3.0 cm in length x 1.0 cm in diameter and has a herring bone appearance of the mucosa. There is no tumor involvement of the endocervical canal. Representative sections are submitted as follows:

- E1 - E2 Anterior and posterior cervix
- E3 - E4 Anterior and posterior lower uterine segment
- E5 - E7 Anterior endomyometrium
- E8 - E10 Posterior endomyometrium
- E11 - Left fallopian tube and ovary
- E12 - Tumor for
- E13 - Right fallopian tube and ovary
- E14 - Fallopian tube for

Intra-Operative Consultation

Uterus, cervix and BSO (IOC):

- Invasive endometrial carcinoma, about 40-50% invasion with lower uterine segment involvement. Cervix is not involved.
- Benign BSO.

Test performed by

MD

Diagnosis

- A. Lymph node, left periaortic, excision:
- One lymph node negative for metastatic carcinoma (0/1).
- B. Lymph node, right periaortic, excision:
- One lymph node negative for metastatic carcinoma (0/1).
- C. Lymph node, right pelvic, excision:
- Nineteen lymph nodes negative for malignancy (0/19).
- D. Lymph nodes, left pelvic, excision:
- Eight lymph nodes negative for malignancy (0/8).
- E. Uterus with cervix and bilateral adnexa, total hysterectomy and bilateral salpingo-oophorectomy:
- Poorly-differentiated endometrioid adenocarcinoma of the endometrium with extensive necrosis (FIGO 3).
- Myometrial invasion of 67%.
- Focal involvement of the lower uterine segment; no invasion.
- Focal secretory change and stromal decidualization consistent with progestin effect.
- Small leiomyoma.
- Focal serosal endosalpingiosis.

[page 3 of 3]
Surgical Pathology Report
Temporary Copy

Page 3 of 3

Case
Collected
Ordered by

Patient
ID
Location

- Mild chronic cervicitis and immature squamous metaplasia of the uterine cervix.
- Unremarkable left and right ovaries.
- Multiple paratubal cysts and cystic Walthard rests of the left and right fallopian tubes.

Electronically signed

Comments

Selected slides from this case were also reviewed at the

on

SUMMARY

Type of surgery:	Total hysterectomy and bilateral salpingo-oophorectomy
Gross size of tumor:	6.0 cm.
Tumor location:	Corpus; lower uterine segment
Histologic type:	Endometrioid
Histologic grade (FIGO):	3 of 3
Depth of myometrial invasion:	67% (1.6 cm with wall thickness of 2.4 cm)
Cervical involvement:	Absent
Lower uterine segment involvement:	Present; no stromal invasion
Lymphatic space invasion:	Present
Blood vessel invasion:	Not identified
Surgical margins:	Negative
Other tumor site(s):	None

OTHER ENDOMETRIAL PATHOLOGY: None

Pelvic washings: Not performed

LYMPH NODES

Left pelvic:	8 Negative nodes
Right pelvic:	19 Negative nodes
Left para-aortic:	1 Negative node
Right para-aortic:	1 Negative node

AJCC Stage: pT1c N0 MX

Source: NCI Genomic Data Commons file cd6b1056-d7b6-40c0-a6d5-5b87f21981b5 (TCGA-AX-A2HG.EF863B73-4C80-42E6-8AAF-2EF72559212A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).